Somatic mutation profile of tumor specimen TARGET-10-PARCCM-09A (aliquot TARGET-10-PARCCM-09A-01D) from TARGET case TARGET-10-PARCCM, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.1 years (2,576 days).
Specimen TARGET-10-PARCCM-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e3b468d-e402-4479-890e-5a160910928b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARCCM-10A (Blood Derived Normal), aliquot TARGET-10-PARCCM-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4370ab41-a882-48d3-8115-fd662b9f111b

The open-access MAF lists 77 somatic variants for this specimen: 43 protein-altering or splice-affecting, 16 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 16, Intron 8, RNA 5, 3'UTR 3, Frame Shift Ins 2, Nonsense Mutation 2, 5'Flank 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4336C>T p.R1446C | Missense Mutation (SNP) | VAF 6/73 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398124146, COSV52113365, COSV52115600, COSV52116725; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2
- EP300 | c.4195G>A p.D1399N | Missense Mutation (SNP) | VAF 7/14 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519889, COSV54325045, COSV54326888, COSV54344606; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- C7 | c.1204C>T p.R402* | Nonsense Mutation (SNP) | VAF 28/92 reads (30%) | catalogued as rs200365542; called by muse, mutect2, varscan2
- CMTR1 | c.2036G>A p.R679Q | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1360436719, COSV65092011; called by muse, mutect2, varscan2
- CTNNA3 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375721994; called by muse, mutect2, varscan2
- FA2H | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.79); PolyPhen benign (0.015); catalogued as rs202048141; ClinVar: benign; called by muse, mutect2, varscan2
- GP1BA | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs369964931; called by muse, mutect2, varscan2
- GRM1 | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs756771755; called by muse, mutect2, varscan2
- KIAA1210 | c.1945C>T p.P649S | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.391); catalogued as COSV68179547; called by muse, mutect2, varscan2
- NBEA | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100077054; called by muse, mutect2, varscan2
- NXPH1 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs748850462, COSV68314357; called by muse, mutect2, varscan2
- PDZRN3 | c.2740C>T p.P914S | Missense Mutation (SNP) | VAF 56/114 reads (49%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs267599930; called by muse, mutect2, varscan2
- PEG3 | c.4019C>T p.S1340F | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs375753042; called by muse, mutect2, varscan2
- PTPRU | c.3124G>A p.E1042K | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs375188981; called by muse, mutect2, varscan2
- PXDC1 | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs765788763; called by muse, mutect2, varscan2
- SERPINB12 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0.272); catalogued as rs771471690, COSV54033287; called by muse, mutect2, varscan2
- USH2A | c.2717G>A p.G906E | Missense Mutation (SNP) | VAF 71/142 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as rs763744677; called by muse, mutect2, varscan2
- VPS37D | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100265226, COSV100265278; called by muse, mutect2, varscan2
- WDR59 | c.1867-6C>T | Splice Region (SNP) | VAF 25/80 reads (31%) | catalogued as rs762788348; called by muse, mutect2, varscan2
- ZNF184 | c.716G>A p.R239H | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as rs770736899; called by muse, mutect2, varscan2
- ADGRG4 | c.4178C>T p.T1393I | Missense Mutation (SNP) | VAF 74/137 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- ARHGEF38 | c.770C>T p.S257F | Missense Mutation (SNP) | VAF 53/174 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- CEACAM5 | c.871G>C p.V291L | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- COPA | c.3494C>T p.P1165L | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DST | c.20425G>T p.E6809* (on ENST00000361203 / NM_001374722.1; = p.E4506* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 8/29 reads (28%) | called by muse, mutect2, varscan2
- ETV6 | c.1253_1253+1dup | Frame Shift Ins (INS) | VAF 30/76 reads (39%) | called by mutect2, pindel, varscan2
- GRM2 | c.2264A>G p.N755S | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HMGCLL1 | c.770G>A p.G257E | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- KIAA1210 | c.1946C>T p.P649L | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- LTV1 | c.685C>T p.H229Y | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- NAALAD2 | c.1903G>A p.D635N | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NCEH1 | c.797C>T p.A266V (on ENST00000538775; = p.A226V on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- NDNF | c.1456G>A p.D486N | Missense Mutation (SNP) | VAF 39/165 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NLRP12 | c.2880G>C p.L960F | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- OR8G3P | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- PCDHGA8 | c.145T>A p.S49T | Missense Mutation (SNP) | VAF 47/74 reads (64%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- PKD1L3 | c.3650T>G p.M1217R | Missense Mutation (SNP) | VAF 49/82 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- SHTN1 | c.1613C>T p.P538L | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- SPATA3 | c.462_463insG p.T155Dfs*15 | Frame Shift Ins (INS) | VAF 13/46 reads (28%) | called by mutect2, pindel*, varscan2
- SYNE1 | c.18412G>C p.V6138L (on ENST00000367255 / NM_182961.4; = p.V6067L on NM_033071.3) | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TTN | c.7792G>A p.D2598N (on ENST00000591111; = p.D2552N on NM_003319.4) | Missense Mutation (SNP) | VAF 20/44 reads (45%) | PolyPhen benign (0.037); called by muse, mutect2, varscan2
- UMAD1 | c.113C>A p.A38E | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UNC5A | c.431T>A p.I144K | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- ADGRV1 | c.16122C>T p.S5374= | Silent (SNP) | VAF 19/63 reads (30%) | called by muse, mutect2, varscan2
- ANKRD30B | c.3366G>A p.K1122= | Silent (SNP) | VAF 50/140 reads (36%) | catalogued as rs770804485, COSV57701874; called by muse, mutect2, varscan2
- ARHGAP39 | c.1881C>T p.F627= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs138488684; called by muse, mutect2, varscan2
- ARMC5 | c.1797G>A p.G599= | Silent (SNP) | VAF 12/17 reads (71%) | catalogued as rs1281711124; called by muse, mutect2, varscan2
- FAM9C | c.279C>T p.S93= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs148405468; called by muse, varscan2
- KIR3DL3 | c.1161C>T p.C387= | Silent (SNP) | VAF 10/117 reads (9%) | catalogued as rs746405337, COSV99400169; called by muse, mutect2
- MROH2B | c.1800G>A p.Q600= | Silent (SNP) | VAF 25/116 reads (22%) | catalogued as rs1365610660; called by muse, mutect2, varscan2
- NAALAD2 | c.1506C>T p.I502= | Silent (SNP) | VAF 17/42 reads (40%) | called by muse, mutect2, varscan2
- NBEA | c.318G>A p.L106= | Silent (SNP) | VAF 31/69 reads (45%) | called by muse, mutect2, varscan2
- NLGN4Y | c.1317C>T p.T439= | Silent (SNP) | VAF 21/48 reads (44%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.2136C>T p.S712= (on ENST00000540229 / NM_001371097.1; = p.S651= on NM_001009562.4) | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as rs962840213, COSV67440660; called by muse, mutect2, varscan2
- SPARCL1 | c.558G>A p.R186= | Silent (SNP) | VAF 77/248 reads (31%) | called by muse, mutect2, varscan2
- SYN3 | c.693C>T p.F231= | Silent (SNP) | VAF 37/76 reads (49%) | catalogued as rs377467212; called by muse, mutect2, varscan2
- TINAG | c.1392C>T p.I464= | Silent (SNP) | VAF 38/125 reads (30%) | catalogued as rs544720758, COSV52511690; called by muse, mutect2, varscan2
- TRAM1L1 | c.333C>T p.F111= | Silent (SNP) | VAF 48/155 reads (31%) | called by muse, mutect2, varscan2
- ZNF157 | c.612C>T p.Y204= | Silent (SNP) | VAF 52/128 reads (41%) | called by muse, mutect2, varscan2
- AC092821.1 | n.4248C>T | RNA (SNP) | VAF 36/89 reads (40%) | called by muse, mutect2, varscan2
- ACTB | c.363+159C>T | Intron (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2, varscan2
- AGPAT3 | c.1042+79C>T | Intron (SNP) | VAF 11/30 reads (37%) | called by muse, mutect2, varscan2
- ANKS3 | c.-2-61C>T | Intron (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- BAIAP3 | c.1617-36G>A | Intron (SNP) | VAF 29/51 reads (57%) | called by muse, mutect2, varscan2
- C19orf67 | c.*19G>A | 3'UTR (SNP) | VAF 7/16 reads (44%) | called by muse, mutect2, varscan2
- DCAF13 | chr8:103415311 G>A | 5'Flank (SNP) | VAF 9/120 reads (8%) | catalogued as COSV99884203; called by muse, mutect2
- FER1L4 | n.4006G>A | RNA (SNP) | VAF 18/53 reads (34%) | called by muse, mutect2, varscan2
- GNGT1 | c.*37G>A | 3'UTR (SNP) | VAF 6/17 reads (35%) | called by muse, mutect2, varscan2
- KLF7 | c.103-9673C>T | Intron (SNP) | VAF 36/67 reads (54%) | catalogued as rs376495170; called by muse, mutect2, varscan2
- PPP1R1A | c.*16C>T | 3'UTR (SNP) | VAF 9/19 reads (47%) | called by muse, mutect2, varscan2
- SAP30BP | c.660+102C>T | Intron (SNP) | VAF 15/21 reads (71%) | called by muse, mutect2, varscan2
- SLC22A2 | n.825A>G | RNA (SNP) | VAF 17/40 reads (43%) | catalogued as rs993553259; called by muse, mutect2, varscan2
- SLC7A9 | c.236-49G>A | Intron (SNP) | VAF 15/31 reads (48%) | called by muse, mutect2, varscan2
- SSX6P | n.277G>A | RNA (SNP) | VAF 51/135 reads (38%) | catalogued as rs371225152; called by muse, mutect2, varscan2
- TFDP3 | c.-51C>T | 5'UTR (SNP) | VAF 8/21 reads (38%) | called by muse, varscan2
- TRIM29 | c.1705-1089G>A | Intron (SNP) | VAF 9/19 reads (47%) | called by muse, mutect2, varscan2
- XIST | n.7830C>T | RNA (SNP) | VAF 31/59 reads (53%) | called by muse, mutect2, varscan2
